Somatic mutation profile of tumor specimen TCGA-44-A47G-01A (aliquot TCGA-44-A47G-01A-21D-A24D-08) from TCGA case TCGA-44-A47G, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.4 years (26,800 days).
Specimen TCGA-44-A47G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1a3419b-b929-4247-83a1-afd68a3a233e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-A47G-10A (Blood Derived Normal), aliquot TCGA-44-A47G-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c05b85da-cbbf-4bd5-a253-449272fd61a8

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+2T>G p.X1010_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFF2 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100651071; called by muse, mutect2
- ANGEL2 | c.1084A>T p.S362C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV100853993; called by muse, mutect2, varscan2
- ATP6V1A | c.1752G>C p.M584I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56362252; called by muse, mutect2
- CATSPERG | c.2600G>T p.G867V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99286907; called by muse, mutect2, varscan2
- CCDC24 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as rs376940328; called by muse, mutect2, varscan2
- CCIN | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140883913; called by muse, mutect2, varscan2
- CDC5L | c.647T>G p.F216C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101015184; called by muse, mutect2, varscan2
- COL5A2 | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880770; called by muse, mutect2
- COL9A2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV101025773; called by muse, mutect2
- DGKD | c.773G>T p.S258I (on ENST00000264057 / NM_152879.3; = p.S214I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99897525; called by muse, mutect2
- DISP3 | c.1964G>T p.G655V | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99609904; called by muse, mutect2
- EDARADD | c.496G>A p.E166K (on ENST00000334232 / NM_145861.4; = p.E156K on NM_080738.4) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100513093; called by muse, mutect2
- EFL1 | c.378+2T>A p.X126_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99188518; called by muse, mutect2
- FBXO11 | c.1484G>C p.C495S (on ENST00000403359 / NM_001190274.2; = p.C411S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100319971; called by muse, mutect2
- FRMPD4 | c.2383G>C p.E795Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101044014, COSV66213612; called by muse, mutect2
- GBP4 | c.878C>G p.T293S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV100864460, COSV63255434; called by muse, mutect2
- GPR65 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99966154; called by muse, mutect2, varscan2
- HTR3A | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV100248611; called by muse, mutect2
- IFNA10 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV99497584; called by muse, mutect2, varscan2
- INPPL1 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV53358580, COSV99996625; called by muse, mutect2
- KCTD1 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV58686935; called by muse, mutect2
- LCOR | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100603640, COSV100603860; called by muse, mutect2
- LDB2 | c.1120T>G p.*374Eext*31 | Nonstop Mutation (SNP) | VAF 16/216 reads (7%) | catalogued as COSV100454739; called by muse, mutect2
- MAGI1 | c.3793G>A p.D1265N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as COSV100443032; called by muse, mutect2
- MRAS | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100003937; called by muse, mutect2, varscan2
- MYH2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV55438753; called by muse, mutect2, varscan2
- NAT10 | c.1896C>A p.H632Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99140476; called by muse, mutect2
- NEK5 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100839299; called by muse, mutect2, varscan2
- OR2A12 | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs757029810, COSV101283205; called by muse, mutect2, varscan2
- OR2T10 | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100393795; called by muse, mutect2
- OR6F1 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129018; called by muse, mutect2
- P4HTM | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100637617; called by muse, mutect2, varscan2
- PCDHB2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.052); catalogued as COSV50570897; called by muse, mutect2, varscan2
- PLEKHH2 | c.3184C>A p.L1062I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs956809349, COSV99175083; called by muse, mutect2
- PNPLA4 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as rs372843326, CM161321, COSV66854267; called by muse, mutect2
- PRUNE2 | c.6583A>G p.I2195V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65040585; called by muse, mutect2, varscan2
- RPGR | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100140419; called by muse, mutect2
- SEMA6B | c.764T>G p.L255R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100015110; called by mutect2, varscan2
- SLC9A4 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99763523; called by muse, mutect2, varscan2
- SLITRK5 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100281185; called by muse, mutect2, varscan2
- SPANXN3 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100980873; called by muse, mutect2
- SPTBN2 | c.7149C>A p.F2383L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100018144, COSV100020429; called by muse, mutect2
- STARD13 | c.2981C>T p.T994I (on ENST00000336934 / NM_001243476.3; = p.T876I on NM_052851.3) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99716357; called by muse, mutect2
- TGFBRAP1 | c.1996C>G p.P666A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99305512; called by muse, mutect2
- TRIM21 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs757789140, COSV99587902; called by muse, mutect2
- TRIM46 | c.119A>T p.Y40F | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV99826085; called by muse, mutect2
- TUBB6 | c.1229A>C p.E410A | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1316265234, COSV99302158; called by muse, mutect2
- ZNF343 | c.1647C>A p.Y549* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99601643; called by muse, mutect2
- ZNF462 | c.2325A>T p.R775S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99473215; called by muse, mutect2
- ZXDA | c.1504A>T p.I502F | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100699465; called by muse, mutect2
- ATP2B3 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- HEATR9 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- PDYN | c.206dup p.T70Hfs*9 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- RNF139 | c.1735C>G p.Q579E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- STARD13 | c.1664dup p.T556Nfs*4 (on ENST00000336934 / NM_001243476.3; = p.T438Nfs*4 on NM_052851.3) | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by mutect2, varscan2
- ABCC3 | c.1350C>T p.P450= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- CNN2 | c.786C>T p.F262= | Silent (SNP) | VAF 18/241 reads (7%) | catalogued as rs575306222, COSV99566614; called by muse, mutect2
- CXCL9 | c.300G>A p.K100= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99345747, COSV99345831; called by muse, mutect2
- EIF4A2 | c.1086C>T p.G362= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1253450588, COSV99961369; called by muse, mutect2, varscan2
- HELZ | c.2115C>G p.L705= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100699040; called by muse, mutect2
- HOXA3 | c.1011G>T p.G337= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100415678; called by muse, mutect2, varscan2
- MYO15A | c.921C>T p.Y307= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1419296334, COSV52759618; called by muse, mutect2, varscan2
- OR2A5 | c.813G>A p.Q271= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs753466523, COSV101278845, COSV68738604; called by muse, mutect2
- PIKFYVE | c.300C>T p.L100= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100011398; called by muse, mutect2
- PKLR | c.753C>T p.G251= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1459538361, COSV61360629; called by muse, mutect2, varscan2
- TIGD7 | c.1182C>T p.T394= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1441150355, COSV99239999; called by muse, mutect2
- TRIM39 | c.108G>A p.L36= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100935908; called by muse, mutect2
- XIRP1 | c.2833C>A p.R945= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100453949; called by muse, mutect2, varscan2
- POFUT1 | c.542+293G>A | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100998404, COSV99058640; called by muse, mutect2
